Somatic mutation profile of tumor specimen TCGA-AX-A0IS-01A (aliquot TCGA-AX-A0IS-01A-12D-A10M-09) from TCGA case TCGA-AX-A0IS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G2; Age at diagnosis: 52.5 years (19,173 days).
Specimen TCGA-AX-A0IS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df1a6037-bba7-40ff-81a0-9fef8fd3b530.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A0IS-10B (Blood Derived Normal), aliquot TCGA-AX-A0IS-10B-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52796f1a-87aa-4f24-801d-730493c3758d

The open-access MAF lists 56 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 39, Silent 10, Frame Shift Del 4, In Frame Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 31/68 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ESR1 | c.1609T>A p.Y537N | Missense Mutation (SNP) | VAF 33/86 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52784978, COSV52804811, COSV99237981; called by muse, mutect2, varscan2
- PIK3R1 | c.1719_1721del p.R574del (on ENST00000521381 / NM_181523.3; = p.R304del on NM_181504.4) | In Frame Del (DEL) | VAF 142/248 reads (57%) | hotspot (GDC flag); catalogued as COSV57130543; called by mutect2, pindel, varscan2
- AATK | c.440G>T p.G147V (on ENST00000326724 / NM_001080395.3; = p.G44V on NM_004920.2) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58688206; called by muse, mutect2, varscan2
- AHNAK | c.10306G>A p.A3436T | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV57214211; called by muse, mutect2, varscan2
- APOD | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as rs757719233, COSV58402036; called by muse, mutect2, varscan2
- ARHGEF1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369826806, COSV61526868; called by muse, mutect2, varscan2
- ARID1A | c.1274del p.Q425Rfs*8 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as COSV61378098; called by mutect2, pindel, varscan2
- BIK | c.94A>C p.M32L | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53337493; called by muse, mutect2, varscan2
- CES1 | c.964G>C p.V322L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs779846465, COSV62087051; called by muse, mutect2, varscan2
- CLMN | c.1886_1887del p.H629Rfs*11 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | catalogued as COSV54182372; called by mutect2, pindel, varscan2
- CPNE9 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs190521882; called by muse, mutect2, varscan2
- CRH | c.467A>C p.E156A | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV52542126; called by muse, mutect2, varscan2
- CUX2 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55632752; called by muse, mutect2, varscan2
- E2F1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58534410; called by muse, mutect2, varscan2
- FARS2 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 73/135 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223957, COSV51165671; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FZD9 | c.1587G>T p.W529C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV59991320; called by muse, mutect2, varscan2
- GAL3ST4 | c.1217A>G p.H406R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV57586458; called by muse, mutect2, varscan2
- GPRASP2 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.205); catalogued as COSV59991366; called by muse, mutect2, varscan2
- GSPT2 | c.1574A>C p.Q525P | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61214394; called by muse, mutect2, varscan2
- IMPG1 | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV64057971, COSV64062554; called by muse, mutect2, varscan2
- INPP5B | c.1981A>C p.K661Q (on ENST00000373023; = p.K581Q on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65960949; called by muse, mutect2, varscan2
- IRS4 | c.2740G>T p.E914* | Nonsense Mutation (SNP) | VAF 86/229 reads (38%) | catalogued as COSV64533907; called by muse, mutect2, varscan2
- KCNJ9 | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV63631822; called by muse, mutect2
- KIAA0232 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV56925505; called by muse, mutect2, varscan2
- MIB2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as rs368773238, COSV61755837; called by muse, mutect2, varscan2
- MRGPRF | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1163843209, COSV57995922; called by muse, mutect2, varscan2
- PCDHA3 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.055); catalogued as rs941404430, COSV63541783; called by muse, mutect2, varscan2
- PIK3R1 | c.1254del p.K419Nfs*4 (on ENST00000521381 / NM_181523.3; = p.K149Nfs*4 on NM_181504.4) | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | catalogued as COSV57135492; called by mutect2, pindel, varscan2
- POLR1A | c.3262G>A p.A1088T | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs370878679; called by muse, mutect2, varscan2
- PTEN | c.901del p.D301Ifs*6 | Frame Shift Del (DEL) | VAF 75/112 reads (67%) | catalogued as COSV64297131; called by mutect2, pindel, varscan2
- PTGFR | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV66114470; called by muse, mutect2, varscan2
- RHAG | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs1411229670, COSV57704420; called by muse, mutect2, varscan2
- SCRIB | c.953A>G p.N318S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746406445, COSV57587199; called by muse, mutect2, varscan2
- SLC7A14 | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1018189773, COSV51582285; called by muse, mutect2, varscan2
- SLITRK3 | c.1893C>A p.H631Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.068); catalogued as COSV53848641; called by muse, mutect2, varscan2
- ST8SIA3 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 35/82 reads (43%) | PolyPhen probably damaging (1); catalogued as rs1568101404, COSV60653938; called by muse, mutect2, varscan2
- STAC | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs1384065882, COSV56206657; called by muse, mutect2, varscan2
- TMEM87A | c.165T>G p.F55L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.523); catalogued as COSV56197955; called by muse, mutect2, varscan2
- TRHDE | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1300960136, COSV53845146; called by muse, mutect2, varscan2
- TTN | c.21405G>C p.W7135C (on ENST00000591111; = p.W6208C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | PolyPhen probably damaging (1); catalogued as COSV60074935; called by muse, mutect2
- VIPR1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs193233046, COSV57297475; called by muse, mutect2, varscan2
- ZBTB10 | c.1168_1169dup p.T391Rfs*20 | Frame Shift Ins (INS) | VAF 28/104 reads (27%) | catalogued as COSV66947189; called by mutect2, pindel, varscan2
- ZFHX4 | c.7832C>T p.T2611M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50830947; called by muse, mutect2, varscan2
- ZMYND10 | c.94T>G p.W32G | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1401265243; called by muse, mutect2
- ZSCAN5B | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.974); catalogued as rs373469763; called by muse, mutect2, varscan2
- C2orf80 | c.99G>A p.R33= | Silent (SNP) | VAF 82/183 reads (45%) | catalogued as COSV58016841; called by muse, mutect2, varscan2
- DBP | c.861G>A p.A287= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV55337613; called by muse, mutect2, varscan2
- DOCK10 | c.1401C>T p.I467= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as rs572940550, COSV51400739; called by muse, mutect2, varscan2
- GABRA3 | c.1104T>G p.A368= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV64799025; called by muse, mutect2, varscan2
- KDM1B | c.1035C>T p.C345= (on ENST00000449850; = p.C213= on NM_153042.4) | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs766865830, COSV52810997; called by muse, mutect2, varscan2
- PRR23B | c.348C>T p.H116= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV61493169; called by muse, mutect2, varscan2
- PRSS55 | c.381C>T p.N127= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs771081101, COSV60808364; called by muse, mutect2, varscan2
- SLC22A14 | c.1686G>A p.T562= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs762351993, COSV56197770, COSV99828198; called by muse, mutect2, varscan2
- SPANXC | c.24C>T p.G8= | Silent (SNP) | VAF 120/210 reads (57%) | catalogued as rs781784428; called by mutect2, varscan2
- USP7 | c.285G>A p.L95= | Silent (SNP) | VAF 86/199 reads (43%) | catalogued as rs759100414, COSV61214764; called by muse, mutect2, varscan2
